Gene-level copy-number profile of tumor specimen TCGA-AR-A1AP-01A from TCGA case TCGA-AR-A1AP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 80.5 years (29,406 days).
Specimen TCGA-AR-A1AP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.81e9397d-c246-4d14-a6e9-f3e068e8c43f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ea0a41c-b56e-4387-ada1-de0df1d437d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 15,471; copy number 2: 38,318; copy number 3: 5,562; copy number 4: 62; copy number 5: 31; copy number 6: 221; copy number 7: 32; copy number 8: 55; copy number 9: 9; copy number 11: 34; copy number 15: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AP-01A-11D-A12N-01): tumor purity 0.7, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:12,549,764–12,642,854, 2 genes: LINC00670, AC068442.1.
- chr18:23,197,144–23,982,556, 13 genes (within-gene range 0–1): TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1.
- chr18:23,994,213–24,015,339, 1 gene: TTC39C-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 390 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,000,765–75,241,173, 221 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:75,562,056–81,556,425, 106 genes, copy number 5–11 (broad region; genes not listed).
- chr11:81,842,435–81,987,813, 3 genes, copy number 7: AP002802.2, MIR4300, AP002802.1.
- chr11:85,509,938–86,672,636, 26 genes, copy number 5 (within-gene range 1–5): RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3.
- chr11:87,648,489–89,065,945, 22 genes, copy number 8–15 (within-gene range 1–15): U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3, AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P.
- chr11:89,498,748–89,727,253, 12 genes, copy number 7: H3P34, AP003400.4, AP003400.5, AP003400.1, AP003400.2, AP003400.3, AP003400.6, FOLH1B, UBTFL10, AP003122.6, TRIM77, AP003122.4.

Autosomal genes at a single copy (total copy number 1): 13,117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
